TARGET case TARGET-40-NAAHAA — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/7a469405-d7ad-5ff1-ae82-2fa4f53b8c62

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; Tissue or organ of origin: Bone, NOS; Site of resection or biopsy: Long bones of lower limb and associated joints; Age at diagnosis: 19.1 years (6,970 days); Year of diagnosis: 2010; Days to last follow up: 1,771 days (4.8 years).
